Gene-level copy-number profile of tumor specimen HTMCP-03-06-02341-01A from CGCI case HTMCP-03-06-02341, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 48.7 years (17,784 days).
Specimen HTMCP-03-06-02341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92268c54-fd7d-4eac-8680-6b17bfbbbec3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02341-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/d905c85a-5068-4242-a36a-19c53f116a83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 17,614; copy number 2: 30,161; copy number 3: 6,510; copy number 4: 565; copy number 5: 2,668; copy number 6: 265; copy number 7: 501; copy number 8: 47; copy number 10: 3; copy number 12: 14.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr22:25,279,529–25,520,854, 12 genes: AL022332.1, AL022324.4, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,498 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 6–10 (broad region; genes not listed).
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr7:38,239,580–38,340,998, 17 genes, copy number 5: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 5 (within-gene range 1–5): TRGV5P, TRGV5, TRGV4.
- chr14:21,978,459–22,492,907, 61 genes, copy number 5–8 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr14:106,850,885–106,879,812, 6 genes, copy number 6: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:38,297,023–39,747,291, 68 genes, copy number 7–12 (broad region; genes not listed).
- chr19:27,638,483–58,605,223, 1,672 genes, copy number 5 (broad region; genes not listed).
- chr20:22,220,554–64,327,972, 985 genes, copy number 5–6 (broad region; genes not listed).
- chr21:12,999,676–13,120,807, 5 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 15,270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
